Somatic mutation profile of tumor specimen MMRF_1992_1_BM_CD138pos (aliquot MMRF_1992_1_BM_CD138pos_T1_KBS5U_L07272) from MMRF case MMRF_1992, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,595 days).
Specimen MMRF_1992_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff20235-2990-4244-932b-fd814694aab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1992_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1992_1_PB_CD3pos_C5_KBS5U_L07274; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc507b0b-a344-4f62-b343-28305f71a6c4

The open-access MAF lists 33 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 10, 5'UTR 3, Intron 3, 3'Flank 2, 5'Flank 1, Silent 1, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.3194C>A p.A1065E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770471782, CM114376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELK1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1418561205, COSV55953509; called by muse, mutect2, varscan2
- PRMT1 | c.643+6C>T | Splice Region (SNP) | VAF 20/165 reads (12%) | catalogued as rs372587638; called by muse, mutect2, varscan2
- ADAMTS2 | c.2169A>T p.K723N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10A | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GRWD1 | c.111_127del p.G38Rfs*27 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- INTS8 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MISP | c.1591G>C p.A531P | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RSPH10B | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2
- SYNCRIP | c.1280T>A p.M427K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); called by muse, mutect2
- TRIM65 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSHR | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNJL | c.915C>T p.A305= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs745814652, COSV57445825; called by muse, mutect2, varscan2
- ABHD14A | chr3:51973844 G>A | 5'Flank (SNP) | VAF 16/29 reads (55%) | catalogued as rs1199787106; called by muse, mutect2, varscan2
- ADAM22 | c.993-308A>T | Intron (SNP) | VAF 15/130 reads (12%) | called by mutect2, varscan2
- ANKRD45 | c.-39C>G | 5'UTR (SNP) | VAF 66/149 reads (44%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-213A>G | 5'UTR (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- ATP2A1 | c.*210A>C | 3'UTR (SNP) | VAF 79/220 reads (36%) | called by muse, mutect2, varscan2
- CARMIL3 | c.*224T>C | 3'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, varscan2
- CDK12 | c.-2G>T | 5'UTR (SNP) | VAF 22/44 reads (50%) | catalogued as COSV101420441; called by muse, varscan2
- CST9 | c.*376C>T | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- DELE1 | chr5:141940633 C>A | 3'Flank (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- DNM1P46 | n.970C>T | RNA (SNP) | VAF 17/49 reads (35%) | catalogued as rs375152504; called by muse, mutect2, varscan2
- DYNLL1 | c.133-127T>C | Intron (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- FAM172A | c.*1676A>G | 3'UTR (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- MYO15B | c.7984-38G>A | Intron (SNP) | VAF 27/50 reads (54%) | catalogued as rs922216903; called by muse, mutect2, varscan2
- PDK4 | c.*750T>C | 3'UTR (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- PIK3C2A | c.*1095T>G | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- SOX4 | c.*1156A>G | 3'UTR (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.*359A>G | 3'UTR (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- WDR37 | c.*2655G>C | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- ZNF561 | c.*2041G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by mutect2, varscan2
- ZNF773 | chr19:57513079 C>T | 3'Flank (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
